Gene-level copy-number profile of specimen HCM-BROD-0418-C71-85B from HCMI case HCM-BROD-0418-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 45.5 years (16,625 days).
Specimen HCM-BROD-0418-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a8e1050b-64a4-4ca1-af1d-55009e10f49c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0418-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/b53e647c-f2d5-4130-b526-5fd852d159b7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 69; copy number 1: 77; copy number 2: 6,012; copy number 3: 8,746; copy number 4: 37,756; copy number 5: 3,098; copy number 6: 152; copy number 7: 121; copy number 8: 2,860; copy number 10: 7; copy number 11: 6.

Homozygous deletions (total copy number 0; autosomes only): 69 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,331,446–22,214,672, 65 genes (broad region; genes not listed).
- chr9:29,254,075–29,826,711, 4 genes: AL162388.1, AL353684.1, AL354676.1, ME2P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,933,699–55,260,256, 6 genes, copy number 11: AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr7:76,510,525–76,627,982, 7 genes, copy number 10: UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16, AC004980.1, POMZP3.

Autosomal genes at a single copy (total copy number 1): 77. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
